Surgical pathology report (de-identified scan), TCGA case TCGA-K7-AAU7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K7-AAU7-01A (Primary Tumor).

[page 1 of 4]
MRN
Name
Encounter Number

Gender
Date Of Birth

M

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

ICD-O-3

Results

Hepatobiliary carcinoma 8180/3
Site: Liver C22.0
Q5 5/30/14

Final

Source of Specimen
SEGMENT 2 & 3 LIVER-

FINAL DIAGNOSIS:
SEGMENT 2 & 3 LIVER-
COMBINED HEPATOCELLULAR-CHOLANGIOCARCINOMA, MODERATELY
DIFFERENTIATED.

TUMOR LOCATION: SEGMENTS 2 AND 3 OF LIVER.

TUMOR FOCALITY: UNIFOCAI.

TUMOR SIZE (LARGEST FOCUS, IF MULTIFOCAI): 3.8 CM.

LYMPH-VASCULAR INVASION:

MACROSCOPIC VENOUS INVASION: NOT PRESENT.

MICROSCOPIC SMALL VESSEL/LYMPHATIC INVASION: IS PRESENT,
EXTENSIVE.

INVASION OF MAJOR BRANCH OF PORTAL OR HEPATIC VEINS: NOT
PRESENT.

TNM STAGE: pT2a, pNX, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: N/A

SATELLITE LESION: IS PRESENT.

(satellite lesion is a tumor nodule <4.0 cm in diameter, <2.0 cm
from the primary tumor, and <50% of the primary tumor's

Prepared for

[page 2 of 4]
diameter)

TUMOR NECROSIS: NONE.

SPECIMEN TYPE: SEGMENTECTOMY.

THE TUMOR IS FOCALLY PRESENT AT THE CAUTERIZED INKED PARENCHYMAL RESECTION MARGIN.

TUMOR IS ALSO SEEN IN VASCULAR SPACES WITHIN 2-3 MM TO THE RESECTION MARGIN.

HILAR STRUCTURES NEGATIVE FOR TUMOR.

SPECIMEN SIZE: 18.0 X 10.0 X 6.0 CM.

TIPS: NO

OTHER FINDINGS:

CIRRHOSIS WITH MILD TO MODERATE STEATOSIS CONSISTENT WITH CHRONIC HEPATITIS C, GRADE 2/4, STAGE 4/4.

BILE DUCT HAMARTOMA.

IRON STAINING : MILD IRON DEPOSITION IN KUPFFER CELLS AND FOCALLY HEPATOCYTES.

Note: By immunohistochemistry, the majority of the tumor cells are positive for CK7 and CK19. Heppar, Arginase-1 and glypican -3 are focally positive.

These findings support the above diagnosis.

Internal positive elements were examined and/or appropriate positive controls were stained along side sections from this case. The control tissue was examined and judged to be technically acceptable.

Signature

(Case signed

Signed Others

Frozen Section

SEGMENT 2 AND 3 LIVER (GROSS EXAM)- 3 X 2.5 X 2.3 CM, WELL CIRCUMSCRIBED SOLID NODULE SURROUNDED BY THIN CAPSULE.

FS Performed by

Prepared for

on

[page 3 of 4]
(Frozen Section Signed

Case Clinical Information

Gross Description

Received in formalin labeled with the patient's name and "segment 2 and 3 liver" is a portion of liver labeled as segments 2 and 3 weighing 550 grams overall measuring 18 x 10 x 6 cm in dimensions with a parenchymal resection margin measuring 12 x 4 cm, previously inked black. The exterior of the liver has a finely uniformly nodular appearance. The specimen has previously been partially serially sectioned revealing a pale-brown nodular parenchyma together with a single firm white tumor abutting the capsule measuring 3.8 x 2.5 x 1.2 cm in greatest dimension. The nodule focally approaches the inked parenchymal margin. A 4 mm nodule is also present separated from the main tumor by 3 mm of grossly benign liver. A cluster of sutures is identified in the parenchyma 2 cm remote from the tumor. Section code: A1-A2= complete cross section of tumor in relationship to inked parenchymal resection margin; A3-A4= tumor in relationship to small satellite nodule; A5-A11= extensive sampling of tumor in relationship to inked parenchymal resection margin, extensively submitted; A12= shaved, sutured tubular structures at resection margin; A13= representative section of hepatic parenchyma remote from tumor. No additional tumors

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1 AA RECUT
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
A. AA ROUTINE H&E X1 BLOCK.5
H&E X1 ARG-1 CK 7 CK19 GLYP-3 HEP PAR
A. AA ROUTINE H&E X1 BLOCK.6
H&E X1

Prepared for

[page 4 of 4]
A. AA ROUTINE H&E X1 BLOCK.7
H&E X1 AA RECUT
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1
A. AA ROUTINE H&E X1 BLOCK.9
H&E X1
A. AA ROUTINE H&E X1 BLOCK.10
H&E X1
A. AA ROUTINE H&E X1 BLOCK.11
H&E X1
A. AA ROUTINE H&E X1 BLOCK.12
H&E X1 A RECUTS
A. AA ROUTINE H&E X1 BLOCK.13
H&E X1 FE

Prepared for

Source: NCI Genomic Data Commons file c12f8c28-f1dc-4c76-b719-5bcd6dffb7a1 (TCGA-K7-AAU7.AE0DD792-F1D5-4340-A521-FC814E08C0CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).